Surgical pathology report (de-identified scan), TCGA case TCGA-L9-A8F4, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Candler, specimen TCGA-L9-A8F4-01A (Primary Tumor).

[page 1 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

Lab Database:

PATIENT:

ACCT #:

LOC:

REG DR:

AGE/SX:

ROOM:

DOB:

BED:

STATUS:

SPEC #:

RECD:

STATUS:

PERFORMED AT:

COLL:

TIME IN FORMALIN:

hrs.

COLD ISCHEMIA TIME: 0:00

mins.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Adenocarcinoma

Remarks: Tissue banking

Specimen(s): A. Left upper wedge

B. Left pleural biopsy

C. Level 5 lymph node

MICROSCOPIC DIAGNOSIS

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: @ Lung, upper lobe C34.1
JW 5/21/14

A. LUNG, LEFT UPPER LOBE, WEDGE RESECTION:

- INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA
- TUMOR MEASURES 2.7 CM IN GREATEST DIMENSION AND INVADES VISCERAL PLEURA (pT2)
- INTRATUMORAL LARGE VESSEL INVASION IDENTIFIED
- PARENCHYMAL MARGIN NEGATIVE AND MEASURES 8 MM

B. TISSUE SUBMITTED AS LEFT PLEURAL BIOPSY:

- CAUTERIZED CHEST MUSCULAR WALL AND PLEURAL TISSUE WITH CHRONIC INFLAMMATION
- NEGATIVE FOR CARCINOMA

C. LEVEL V LYMPH NODE, RESECTION:

- TWO (2) ANTHRACOTIC LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA

COMMENT(S)

The mass is an invasive poorly differentiated adenocarcinoma. The visceral pleura is extensively involved by the tumor with ink present on tumor at the surface. Within the mid portion of the tumor is an area of necrosis with venous invasion noted.

CAP PROTOCOL FOR THE EXAMINATION OF SPECIMENS WITH PRIMARY NON-SMALL CELL CARCINOMA, SMALL CELL CARCINOMA OR CARCINOID TUMOR OF THE LUNG
BASED ON AJCC/UICC TNM 7TH EDITION

SPECIMEN:

Lung

PROCEDURE:

Wedge resection

SPECIMEN INTEGRITY:

Intact

SPECIMEN LATERALITY:

Left

TUMOR SITE:

Upper lobe

TUMOR SIZE:

Greatest dimension: 2.7 cm

TUMOR FOCALITY:

Unifocal

** CONTINUED ON NEXT PAGE **

[page 2 of 3]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry
Lab Database:

PAGE 2

SPEC #: [REDACTED] PATIENT: [REDACTED] (Continued)

COMMENT(S)

(Continued)

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G3: poorly differentiated
VISCERAL PLEURA INVASION: Present
MARGINS: If all margins uninvolved by invasive carcinoma:
Distance of invasive carcinoma from closest margin:
8 mm parenchymal
TREATMENT EFFECT: Not applicable
LYMPH-VASCULAR INVASION: Present
PATHOLOGIC STAGING: Primary tumor: pT2a
Regional lymph nodes: pN0
Number of lymph nodes examined: 2
Number of lymph nodes involved: 0
Distant metastasis: Not applicable

GROSS DESCRIPTION:

The specimen is received in three parts. Each part is labeled with the patient's name

A. Received fresh for tissue banking with tissue collected at 9 a.m. for tissue banking and designated "left upper wedge" is a 31 gram, 14.0 x 3.5 x 2.0 cm wedge of lung tissue. The pleura is mottled and pink-tan with a focally puckered lesion. The area of puckering corresponds to an indurated tumor mass. The puckered area is 2.5 cm. Staples are removed with the staple margin inked black. The pleural surface is inked blue. The wedge is sectioned to have a 2.7 x 2.0 x 2.0 cm indurated tumor mass. The tumor diffusely involves the pleural surface in the region of puckering and comes to within 1.0 cm of the black inked staple margin. The tumor has a tan-white to mottled gray-black and anthracotic appearance. The lung parenchyma adjacent to the tumor has a spongy, loose consistency with dilated air spaces consistent with possible emphysemic changes. Sections of the tumor are sampled for tissue banking with the tissue collected at [REDACTED]. The remainder of the lung wedge biopsy is sectioned to have a spongy, focally golden-yellow to tan-brown appearing cut surface. No additional lesions are identified. Representative sections are sampled to include the tumor to the nearest inked staple margin and puckered pleura in cassettes A1-A5 with A5 being a random representative section of the parenchyma at the opposite pole of the wedge sampled.

B. Labeled "left pleural biopsy" is a 1.5 x 0.9 x 0.7 cm indurated fibroconnective tissue biopsy. The biopsy has focal adherent clotted blood. The specimen is bisected and entirely submitted in cassette B1.

C. Labeled "level 5 lymph nodes" are two anthracotic, red-brown, nodular lymphoid tissue fragments. The nodes are 6.0 x 0.3 x 0.3 cm and 0.8 x 0.3 x 0.2 cm. The tissues are submitted in toto in cassette C1.

INTRAOPERATIVE CONSULTATION:

A. LEFT UPPER LOBE WEDGE:

- TUMOR PRESENT, ADEQUATE FOR TISSUE BANKING WITH TISSUE PROVIDED TO TISSUE BANK COORDINATOR

** CONTINUED ON NEXT PAGE **

[page 3 of 3]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry
Lab Database:

PAGE 3

SPEC #:

PATIENT:

(Continued)

INTRAOPERATIVE CONSULTATION: (Continued)

PHOTO DOCUMENTATION

Image . Picture Copy Error
Image . Picture Copy Error

Signed ____ (signature on file) ____ 3

** END OF REPORT **

HPA Discrepancy		✓
Prior History		✓

Source: NCI Genomic Data Commons file c47fd82f-768f-4500-9ef4-ac7c11764e41 (TCGA-L9-A8F4.FB592A19-E23C-465D-AEF4-55B9BBF7D486.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).